FM case AD5656 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/03cf3606-cd7c-41ca-b594-e33c7fa236a7

Male, 71.4 years: Papillary carcinoma, NOS (ICD-O-3 8050/3) of the thyroid gland; metastasis biopsied or resected from the head, face or neck. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
